Gene-level copy-number profile of tumor specimen TCGA-CM-6677-01A from TCGA case TCGA-CM-6677, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Hepatic flexure of colon; AJCC pathologic stage: Stage IIA; Age at diagnosis: 75.5 years (27,575 days).
Specimen TCGA-CM-6677-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-COAD.9ce1996e-6182-4574-83d3-942fcec747b8.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-CM-6677-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 803 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/af7a66ab-1dad-494e-9873-c2b76963cbd6

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 2; copy number 1: 368; copy number 2: 4,130; copy number 3: 11,164; copy number 4: 24,276; copy number 5: 12,386; copy number 6: 4,645; copy number 7: 1,391; copy number 9: 1,458.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-CM-6677-01A-11D-1834-01): tumor purity 0.49, ploidy 3.87, whole-genome doublings 2.

Homozygous deletions (total copy number 0; autosomes only): 2 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr18:39,622,123–39,665,494, 2 genes: MIR924, AC099845.1.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 1,458 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr20:87,250–64,313,132, 1,458 genes, copy number 9 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 368. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
